Surgical pathology report (de-identified scan), TCGA case TCGA-BR-6707, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-6707-01A (Primary Tumor).

[page 1 of 2]
Formatted Path Report

STOMACH TISSUE CHECKLIST

Specimen type: Subtotal gastrectomy
Tumor site: Stomach
Tumor size: 7.5 x 0 x 0 cm
Tumor features: Ulcerated
Histologic type: Adenocarcinoma
Histologic grade: Poorly differentiated
Tumor extent: Subserosa
Lymph nodes: 0/15 positive for metastasis (Lesser and greater curvature 0/15)
Lymphatic invasion: Not specified
Venous invasion: Absent
Perineural invasion: Not specified
Margins: Uninvolved
Evidence of neo-adjuvant treatment: Not specified
Additional pathologic findings: Not specified
Comments: None

[page 2 of 2]
Date of Procurement

Source: NCI Genomic Data Commons file df78384b-af00-49db-b146-5d25d53298ca (TCGA-BR-6707.81DA2F97-9AD7-4E25-8614-314C39850527.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).